Gene-level copy-number profile of tumor specimen TCGA-20-0987-01A from TCGA case TCGA-20-0987, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.0 years (22,287 days).
Specimen TCGA-20-0987-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d0a0712d-97d3-4301-b693-8c55388dda13.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-20-0987-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/515f06d9-56a5-4680-9073-cb29eab9bbab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 13,430; copy number 2: 30,642; copy number 3: 12,198; copy number 4: 2,473; copy number 5: 654; copy number 6: 187; copy number 7: 93; copy number 8: 107; copy number 9: 3; copy number 10: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-20-0987-01A-02D-0428-01): tumor purity 0.48, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,032 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:19,882,395–24,609,328, 148 genes, copy number 5 (broad region; genes not listed).
- chr1:30,711,277–32,458,135, 73 genes, copy number 6 (broad region; genes not listed).
- chr1:32,465,072–32,496,686, 1 gene, copy number 6 (within-gene range 3–6): ZBTB8B.
- chr1:96,721,665–99,969,864, 32 genes, copy number 5 (within-gene range 3–5): PTBP2, DPYD, DPYD-AS1, DPYD-IT1, SEC63P1, RPL26P9, AC114878.1, DPYD-AS2, AC114878.2, MIR137HG, BX005019.1, MIR2682, MIR137, AC104453.1, NFU1P2, LINC01776, AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1, PLPPR4, AL365220.1, LINC01708, PALMD, HMGB3P10, FRRS1, RNU4-75P, Y_RNA, AC096949.1, AGL, AC118553.1.
- chr1:99,978,939–99,979,045, 1 gene, copy number 5: RNU6-750P.
- chr1:103,926,567–105,032,365, 4 genes, copy number 5: AL136455.1, AC092506.1, FTLP17, AL591888.1.
- chr1:107,140,007–107,483,458, 1 gene, copy number 5 (within-gene range 3–5): NTNG1.
- chr1:170,460,453–172,752,924, 51 genes, copy number 6–10: GORAB-AS1, GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9, BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1, FMO1, Y_RNA, HMGB1P11, FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1.
- chr1:176,616,273–176,616,786, 1 gene, copy number 5: PTP4A1P7.
- chr2:18,939,697–19,358,623, 4 genes, copy number 6: AC130814.1, LINC01376, MIR4757, OSR1.
- chr2:134,028,608–134,454,621, 5 genes, copy number 5: AC092623.1, MGAT5, MIR3679, RNA5SP104, EDDM3CP.
- chr2:175,842,887–176,819,180, 32 genes, copy number 5 (within-gene range 4–5): EXTL2P1, AC016751.2, AC016751.1, LNPK, EVX2, HOXD13, HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8, HOXD3, MIR10B, HOXD4, HAGLR, AC009336.1, HAGLROS, HOXD1, MIR7704, AC009336.2, AC016739.1, RPSAP25, MTX2, PPIAP67, LINC01117, AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116, RNU6ATAC14P.
- chr3:167,239,843–169,812,986, 40 genes, copy number 8–10: ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2.
- chr4:121,667,946–123,403,760, 27 genes, copy number 5: ANXA5, TMEM155, PP12613, EXOSC9, CCNA2, BBS7, AC079341.1, TRPC3, AC097533.1, RN7SL335P, KIAA1109, ADAD1, IL2, IL21, IL21-AS1, AC053545.1, CETN4P, BBS12, AC021205.2, FGF2, AC021205.1, AC021205.3, NUDT6, SPATA5, AC026402.1, AC026402.2, SPRY1.
- chr5:38,845,858–41,261,438, 33 genes, copy number 5 (within-gene range 4–5): OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6.
- chr7:111,726,110–112,206,407, 1 gene, copy number 5 (within-gene range 2–5): DOCK4.
- chr7:111,953,653–113,146,330, 23 genes, copy number 5: RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30.
- chr8:59,893,856–63,086,053, 43 genes, copy number 5: AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA.
- chr8:89,243,401–92,144,435, 37 genes, copy number 5–8: RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1.
- chr8:94,371,960–99,877,580, 104 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:115,950,511–116,849,463, 6 genes, copy number 5 (within-gene range 3–5): LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23.
- chr8:117,520,713–121,380,465, 42 genes, copy number 5–6: MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19.
- chr8:125,648,327–128,220,803, 43 genes, copy number 6: AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr9:13,986,175–14,472,407, 8 genes, copy number 7 (within-gene range 4–7): PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1.
- chr10:10,798,397–13,099,652, 35 genes, copy number 5 (within-gene range 4–5): CELF2, LINC00710, AL136369.2, AL136369.1, AL162408.1, CELF2-AS2, AL136320.1, CELF2-AS1, AC026887.1, USP6NL, AL512631.2, AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P, DHTKD1, RNU6-88P, SEC61A2, MIR548AK, NUDT5, CDC123, AL512770.1, RN7SL198P, CAMK1D, AL391314.1, RNU6ATAC39P, AL731559.1, MIR4480, MIR4481, MIR548Q, AL353586.1, CCDC3, RNA5SP300.
- chr11:30,830,369–34,358,010, 67 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:40,083,710–40,112,599, 2 genes, copy number 9: AC021820.1, AC080100.1.
- chr11:40,351,564–40,351,672, 1 gene, copy number 9: Y_RNA.
- chr11:44,047,981–48,628,493, 140 genes, copy number 5 (broad region; genes not listed).
- chr18:76,357,682–76,822,295, 15 genes, copy number 5: ZNF516, AC009716.1, AC009716.2, AC018413.1, ZNF516-DT, LINC00683, AC034110.1, LINC01927, LINC01879, ARL2BPP1, CCND3P2, AC139085.1, ZNF236-DT, RNU6-346P, AC027575.2.
- chr18:76,834,429–76,841,102, 2 genes, copy number 5: RPL26P35, Metazoa_SRP.
- chr21:36,748,626–37,073,170, 10 genes, copy number 5 (within-gene range 3–5): HLCS, HLCS-IT1, RNA5SP491, DPRXP5, AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP.

Autosomal genes at a single copy (total copy number 1): 13,079. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
